Somatic mutation profile of tumor specimen TCGA-EM-A2CS-06A (aliquot TCGA-EM-A2CS-06A-11D-A19J-08) from TCGA case TCGA-EM-A2CS, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, oxyphilic cell; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVA; Age at diagnosis: 52.0 years (18,990 days).
Specimen TCGA-EM-A2CS-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c74bc625-8f85-4f85-ae12-78f585403459.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A2CS-10A (Blood Derived Normal), aliquot TCGA-EM-A2CS-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eed2cc3f-c80f-4c57-978b-e2c3fe18af8c

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ADAMTS9 | c.1959G>T p.Q653H | Missense Mutation (SNP) | VAF 16/179 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99898982; called by muse, mutect2
- ADPGK | c.1481C>T p.P494L | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV100295172, COSV61174029; called by muse, mutect2, varscan2
- BFAR | c.1205C>T p.T402M | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs547915921, COSV99902081; called by muse, mutect2, varscan2
- DLGAP5 | c.2351C>A p.T784N | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.601); catalogued as COSV99903737; called by muse, mutect2, varscan2
- OR2C1 | c.446G>C p.C149S | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV100514881; called by muse, mutect2
- TREX1 | c.856G>A p.G286R (on ENST00000625293 / NM_033629.6; = p.G276R on NM_007248.5) | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.043); catalogued as rs1252684249, COSV99603928; called by muse, mutect2
- SH2D7 | c.888G>A p.G296= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs1199481835, COSV99363144; called by muse, mutect2
